Somatic mutation profile of tumor specimen TARGET-10-PASJYI-09A (aliquot TARGET-10-PASJYI-09A-01D) from TARGET case TARGET-10-PASJYI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.3 years (5,228 days).
Specimen TARGET-10-PASJYI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d108ef6-82a7-400d-9a48-d111f47bfcd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASJYI-10A (Blood Derived Normal), aliquot TARGET-10-PASJYI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e376aa27-9ba9-4cb0-803b-e25ccd8ff2a8

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, 3'UTR 1, Intron 1, Frame Shift Ins 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG8 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762908915, COSV55390511; called by muse, mutect2, varscan2
- ATP8B4 | c.953G>A p.S318N | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs760720943, COSV52708861; called by muse, mutect2, varscan2
- CCDC141 | c.2938G>A p.V980I | Missense Mutation (SNP) | VAF 65/122 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.059); catalogued as COSV55368492; called by muse, mutect2, varscan2
- FAM170A | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58923807; called by muse, mutect2, varscan2
- ITPR2 | c.7465G>A p.V2489M | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV67264302; called by muse, mutect2, varscan2
- MYO5B | c.4202G>A p.R1401Q | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs199722479, COSV53210848; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPN5 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.316); catalogued as COSV62124602, COSV62129528; called by muse, mutect2, varscan2
- RUNX1 | c.343_344insACCCGGGCCGG p.A115Dfs*7 (on ENST00000344691 / NM_001001890.3; = p.A142Dfs*7 on NM_001754.5) | Frame Shift Ins (INS) | VAF 19/57 reads (33%) | catalogued as COSV55888188; called by mutect2, pindel, varscan2
- SALL4 | c.1892G>A p.C631Y | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV53849660; called by muse, mutect2, varscan2
- TNF | c.195G>T p.R65S | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV69304129; called by muse, mutect2, varscan2
- UBR3 | c.415T>A p.S139T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53625820; called by muse, mutect2, varscan2
- USP9X | c.6031C>T p.Q2011* | Nonsense Mutation (SNP) | VAF 62/68 reads (91%) | catalogued as COSV61065654, COSV61071714; called by muse, mutect2, varscan2
- OR2AP1 | c.419T>C p.I140T | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MAGEC3 | c.564G>C p.V188= | Silent (SNP) | VAF 47/48 reads (98%) | catalogued as COSV71610181; called by muse, mutect2, varscan2
- PFDN1 | c.*571G>A | 3'UTR (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2, varscan2
- PRRT2 | c.879+69C>T | Intron (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
